Somatic mutation profile of tumor specimen 0DU4VE from CCDI case PBCHLY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Retinoblastoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 2.7 years (969 days).
Specimen 0DU4VE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7eaf20ff-88e0-4c5d-9a59-bc8fa5a6aaaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU4V0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27148ad0-c974-44b4-96b0-957dfecc9f3f

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARG1 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 326/863 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.408); called by muse, varscan2
- ZNF677 | c.154A>T p.I52F | Missense Mutation (SNP) | VAF 304/800 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, varscan2
- ADAMTSL2 | c.1884G>A p.T628= | Silent (SNP) | VAF 284/1362 reads (21%) | catalogued as rs1488996661; called by muse, varscan2
- BMX | c.*5G>A | 3'UTR (SNP) | VAF 622/1605 reads (39%) | catalogued as rs1400288099; called by muse, varscan2
- ZBTB8OS | c.159-20G>T | Intron (SNP) | VAF 335/698 reads (48%) | catalogued as rs1340613898; called by muse, varscan2
